Surgical pathology report (de-identified scan), TCGA case TCGA-93-A4JQ, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - St. Louis, specimen TCGA-93-A4JQ-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Final

1CD-0-3
adenocarcinoma, acinar 8550/3
Site: Lung, upper lobe
C34.1

hw 10/2/12

SURGICAL PATHOLOGY REPORT FINAL

Patient Name:	[REDACTED]	Service:	Cardiothoracic Surgery	Accession #:	
Address:	[REDACTED]	Location:		Taken:	
Gender:	[REDACTED]	MRN:	[REDACTED]	Received:	
DOB:	[REDACTED]	Hospital #:	[REDACTED]	Accessioned:	
		Patient Type:		Reported:	

Physician(s):

DIAGNOSIS:

- LYMPH NODE, LEVEL 10, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE FRAGMENTED LYMPH NODE (0/1)
- LYMPH NODE, LEVEL 11, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE FRAGMENTED LYMPH NODE (0/1)
- LUNG, RIGHT UPPER LOBE, LOBECTOMY
- INVASIVE ADENOCARCINOMA, ACINAR TYPE, POORLY DIFFERENTIATED (2.3 CM)
- SURGICAL RESECTION MARGINS NEGATIVE
- NO EVIDENCE OF MALIGNANCY IN SIXTEEN PERIBRONCHIAL LYMPH NODES (0/16)
- SEE SYNOPSIS REPORT
- LYMPH NODE, LEVEL IVR, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)
- LYMPH NODE, LEVEL IIR, EXCISION
- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2)
- LYMPH NODE, LEVEL 8, EXCISION
- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2)
- LYMPH NODE, LEVEL VII, EXCISION
- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES (0/4)
- LYMPH NODE, LEVEL 10, EXCISION
- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed On 10/2/12

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to frozen section area is a 'right upper lobe' measuring 18.0 x 12.0 x 3.8 cm and weighing 127.0 grams. The bronchial margin is present as FS1. A subpleural surgical defect measuring 3.0 x 2.0 cm is noted, with underlying tumor. A portion of the tumor (0.8 x 0.4 cm) is taken for TCGA. All for permanents."

FS1: Bronchial margin
- "No evidence of malignancy."

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] with lung cancer. Operative procedure: Right upper lobectomy.

Specimen(s) Received:

- A: LEVEL 10 LYMPH NODE
- B: LEVEL 11 LYMPH NODE
- C: RIGHT UPPER LOBE
- D: LEVEL IV RIGHT LYMPH NODE
- E: LEVEL II RIGHT LYMPH NODE
- F: LEVEL 8I LYMPH NODE
- G: LEVEL VII LYMPH NODE
- H: LEVEL 10 LYMPH NODE

Gross Description:

The specimens are received in eight formalin-filled containers, each labeled [REDACTED]. The first container is labeled "level 10 lymph node." It contains a 1.5 x 0.7 x 0.3 cm aggregate of tan-gray soft tissue fragments, which is submitted entirely in A1. Jar 0.

The second container is labeled "level 11 lymph node." It contains a 1.5 x 1.5 x 0.3 cm aggregate of tan-gray soft tissue fragment, which is submitted entirely in B1. Jar 0.

The third container is labeled "right upper lobe - bronchial margin" and "FS1." It contains a lung lobe, as previously described in the intraoperative consultation section. The attached bronchus measures 1.0 x 0.7 x 0.5 cm. The vein measures 0.8 x 0.2 x 0.2 cm and the artery measures 2.0 x 1.0 x 0.2 cm. The bronchial margin is previously removed and is now received in a blue tissue cassette, which was previously labeled "FS1." The vascular margins are shaved. Multiple hilar lymph nodes are identified. A 15.0 cm staple line is removed and the underlying parenchyma is inked blue. The pleural surface is remarkable for the previously incised area, as described in the intraoperative consultation section. Sections reveal that the mass measures 2.3 x 2.2 x 1.8 cm, directly underlying the pleura. It extends to 2.5 cm from the bronchial and vascular margins, and 1.5 cm from the nearest parenchymal margin. Multiple additional peri-bronchial lymph nodes are identified. Labeled C1 - bronchial margin (FS1); C2 - vascular margin; C3 and C4 - mass to pleura; C5 - additional section of mass; C6 - uninvolved (parenchymal margin); C7 - one lymph node, bisected; C8 to C10 - multiple candidate lymph nodes, intact. Jar 2.

The fourth container is labeled "level IIV lymph node." It contains a 2.0 x 0.5 x 0.3 cm tan-red lymph node, with attached 2.0 x 1.0 x 0.2 cm portion of adipose tissue. Labeled D1. Jar 0.

The fifth container is labeled "level IIR lymph node." It contains a 1.5 x 0.7 x 0.3 cm portion of adipose tissue, with a

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

single 0.2 x 0.2 x 0.2 cm candidate lymph node. Labeled E1. Jar 0.

The sixth container is labeled "level 8 lymph node." It contains a 1.5 x 0.8 x 0.3 cm tan-black candidate lymph node. Labeled F1. Jar 0.

The seventh container is labeled "level VII lymph node." It contains a 1.5 x 1.5 x 0.3 cm aggregate of tan-gray soft tissue fragments, which is submitted entirely in G1. Jar 0.

The eighth container is labeled "level 10 lymph node." It contains a 0.9 x 0.3 x 0.2 cm portion of tan-gray soft tissue which is submitted entirely in H1. Jar 0.

SYNOPTIC REPORTING FORM FOR LUNG CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is adenocarcinoma, acinar (usual) type

HISTOLOGIC GRADE (G)

The grade of the tumor is poorly differentiated (G3)

TUMOR SIZE

The maximum dimension of the tumor is 2.3 cm

LYMPHATIC INVASION

Lymphatic invasion by tumor is absent (L0)

VENOUS INVASION

Venous invasion by tumor is absent (V0)

ARTERIAL INVASION

Arterial invasion by tumor is absent

PLEURAL INVOLVEMENT

Pleural involvement is absent

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are uninvolved by tumor

NON-NEOPLASTIC TISSUE

The non-neoplastic lung tissue shows centrilobular emphysema

PRIMARY TUMOR (T)

Tumor > 2 cm but <= 3 cm in greatest dimension (T1b)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis histologically; no examination for ITC (pN0)

The total number of lymph nodes examined is 28

The total number of metastatically-involved lymph nodes is 0

The lymph node count includes all parts. Multiple lymph nodes contain hyalinized granulomas

DISTANT METASTASIS (M)

Distant metastasis cannot be assessed

STAGE GROUPING

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

The overall international stage is T1b/N0/M0 (Stage IA)

The overall international stage is This synoptic report reflects all parts submitted with this case

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Surgical Pathology report is available on-line

Source: NCI Genomic Data Commons file 05e01ae3-5acf-4831-b3c5-71ed258146a2 (TCGA-93-A4JQ.B9CE532C-BACD-4123-B560-6671CABC5132.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).